Gene-level copy-number profile of tumor specimen HCM-CSHL-0255-C18-01A from HCMI case HCM-CSHL-0255-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: G4.
Specimen HCM-CSHL-0255-C18-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 206b5d87-8f7d-43b8-b0af-2c4163ed38c9.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0255-C18-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,230 have no estimate.
https://portal.gdc.cancer.gov/files/11591b60-ee6f-4b2b-a97b-471a3783a391

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 95; copy number 1: 9,817; copy number 2: 40,880; copy number 3: 4,665; copy number 4: 1,208; copy number 5: 1,390; copy number 6: 247; copy number 7: 3; copy number 8: 76; copy number 9: 12.

Homozygous deletions (total copy number 0; autosomes only): 95 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,266,494–89,310,144, 6 genes: IGKV1-33, IGKV3-34, IGKV1-35, IGKV2-36, IGKV1-37, IGKV2-38.
- chr2:232,378,724–232,387,457, 3 genes: ALPP, AC068134.1, ECEL1P2.
- chr4:112,513,516–112,798,691, 19 genes: NEUROG2, NEUROG2-AS1, RPL23AP94, ZGRF1, H3P14, LARP7, MIR302CHG, MIR367, MIR302D, MIR302A, MIR302C, MIR302B, OSTCP4, AC106864.1, WRBP1, AC017007.3, Y_RNA, RPL7AP30, AC017007.4.
- chr4:112,826,307–112,882,330, 3 genes (within-gene range 0–1): AC017007.2, AC017007.5, AC017007.1.
- chr4:119,405,523–119,454,638, 3 genes: GTF2IP12, AC093752.3, RNU6-1217P.
- chr4:119,456,350–119,457,277, 1 gene (within-gene range 0–1): AC093752.2.
- chr4:127,840,198–128,039,927, 5 genes (within-gene range 0–1): AC093591.2, PLK4, RNU6-583P, MFSD8, ABHD18.
- chr4:128,069,014–128,069,612, 1 gene (within-gene range 0–1): AC099340.1.
- chr5:69,068,925–69,470,136, 19 genes: SUMO2P4, SLC30A5, AC010273.2, AC010273.1, SNORA50D, CCNB1, AC022107.1, CENPH, MRPS36, CDK7, CCDC125, CFL1P5, CHCHD2P2, NDUFB9P1, AK6, TAF9, RAD17, MARVELD2, RPS27P14.
- chr5:69,478,997–69,479,265, 1 gene (within-gene range 0–1): RN7SL616P.
- chr8:7,092,102–7,200,857, 7 genes: AF228730.5, AF228730.2, RPS3AP30, SNRPCP6, SNRPCP15, RPS3AP33, AF228730.1.
- chr9:19,063,656–19,063,786, 1 gene (within-gene range 0–1): SCARNA8.
- chr10:63,110,139–63,521,850, 8 genes (within-gene range 0–1): RNU6-543P, AL590502.1, NRBF2, JMJD1C, TATDN1P1, AC022022.2, MIR1296, PRELID1P3.
- chr10:80,017,713–80,092,557, 8 genes: AL356095.1, C1DP3, C1DP2, C1DP4, TMEM254-AS1, AL356095.3, TMEM254, AL356095.2.
- chr16:33,577,502–33,622,547, 1 gene (within-gene range 0–3): AC142384.1.
- chr18:26,098,839–26,391,685, 9 genes (within-gene range 0–1): RPS24P18, PSMA8, DHFRP1, NPM1P2, TAF4B, SINHCAFP1, AC121320.1, AC022069.1, RNU6-1289P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,728 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:23,169,835–28,778,937, 130 genes, copy number 6 (broad region; genes not listed).
- chr13:79,311,824–80,657,027, 14 genes, copy number 5: RBM26, RNA5SP33, RBM26-AS1, NDFIP2-AS1, NDFIP2, LINC01068, LINC01038, LINC00382, AL158064.1, LINC01080, SPRY2, RNU6-61P, HNRNPA1P31, PWWP2AP1.
- chr13:83,145,540–84,020,762, 6 genes, copy number 5: AL512782.1, RNU6-67P, SLITRK1, AL355481.1, VENTXP2, UBE2D3P4.
- chr13:87,423,493–87,458,407, 1 gene, copy number 6 (within-gene range 4–6): AL360267.2.
- chr13:87,427,214–87,892,472, 8 genes, copy number 6 (within-gene range 4–6): MIR4500HG, AL355578.1, MIR4500, SLITRK5, AL445647.2, LINC00397, AL445647.1, TET1P1.
- chr13:89,833,157–95,301,475, 57 genes, copy number 5–6 (within-gene range 3–6): RPL7L1P1, AL355821.1, PEX12P1, LINC00559, RNA5SP34, FAR1P1, KRT18P27, MIR622, LINC01049, RNU6-75P, LINC00410, BRK1P2, LINC00380, LINC00379, PPIAP23, MIR17HG, MIR17, MIR18A, MIR19A, MIR20A, MIR19B1, MIR92A1, GPC5, AL356118.1, AL162456.1, RNU4ATAC3P, FABP5P4, AL157815.1, GPC5-AS2, AL159152.1, GPC5-IT1, MIR548AS, AL356737.2, AL356737.1, GPC5-AS1, LINC00363, AL354811.1, GPC6, AL160159.1, HNRNPA1P29, GPC6-AS2, RNA5SP35, GPC6-AS1, DCT, TGDS, GPR180, RNA5SP36, LINC00391, RN7SL585P, SOX21-AS1, SOX21, BRD7P5, RPL21P112, LINC00557, AL139381.1, RNU6-62P, ABCC4.
- chr13:95,433,604–103,066,417, 129 genes, copy number 5–9 (broad region; genes not listed).
- chr13:109,478,739–114,337,626, 109 genes, copy number 5–6 (broad region; genes not listed).
- chr16:13,246,232–32,188,107, 672 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr16:49,072,543–53,703,938, 110 genes, copy number 5–6 (broad region; genes not listed).
- chr16:55,007,982–55,956,031, 20 genes, copy number 5: MTND5P34, AC109462.1, RN7SL841P, AC109462.3, IRX6, AC109462.2, RPL31P56, MMP2, AC007336.2, MMP2-AS1, AC007336.3, LPCAT2, AC007336.1, CAPNS2, SLC6A2, AC136621.1, CES1P2, CES1P1, CES1, CES5A.
- chr20:30,214,765–33,309,871, 97 genes, copy number 5 (broad region; genes not listed).
- chr20:46,859,333–51,562,831, 107 genes, copy number 5 (broad region; genes not listed).
- chr20:52,192,159–56,299,160, 41 genes, copy number 5 (within-gene range 4–5): LINC01524, AL109610.1, AL049765.2, AL049765.1, MRPS33P4, AL031674.1, AL121902.1, RPL36P1, TSHZ2, RN7SKP184, AL391097.3, AL391097.1, AL391097.2, AL109930.1, AL354993.1, PPIAP10, AL354993.2, Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC006076.1, SUMO1P1, BCAS1, AC005220.1, MIR4756, CYP24A1, PFDN4, AL133335.1, DOK5, RNU4ATAC7P, RPL12P4, LINC01440, LINC01441, AL160413.1, CBLN4, RNA5SP487, MC3R, AL139824.2, AL139824.1.
- chr20:57,105,741–64,327,972, 227 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 9,805. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
